Somatic mutation profile of tumor specimen 0DWTBO from CCDI case PBCPFD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.9 years (6,548 days).
Specimen 0DWTBO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5388d135-ecbd-4f6f-8ddc-9717f5f2fc78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWTA9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3421718-fa66-4b53-9402-52de0bb0f24b

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 3, Intron 2, Splice Region 1, 5'UTR 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 13/297 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 12/108 reads (11%) | called by muse, varscan2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- STYK1 | c.968-1G>A p.X323_splice | Splice Site (SNP) | VAF 23/234 reads (10%) | called by muse, mutect2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs1267156464; called by muse, varscan2
- C15orf40 | c.*63T>A | 3'UTR (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2
- GLCCI1 | c.696+91A>G | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 6/15 reads (40%) | catalogued as rs1012935800, COSV58726711; called by muse, varscan2
- OR5V1 | c.*5C>G | 3'UTR (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 13/76 reads (17%) | called by muse, varscan2
- TG | c.7239+10186C>A | Intron (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
